Surgical pathology report (de-identified scan), TCGA case TCGA-58-A46K, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-A46K-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, right, lower lobe: 16.0 x 13.0 x 6.5 cm

tumor: 8.5 x 6.5 x 5.0 cm

Diagnosis:

Squamous Cell Carcinoma, partially basaloid

Infiltration of pleura visceralis

pT2, pN2 (5/59), pMx, G3

ICD-O3

carcinoma, squamous cell,
basaloid 8083/3

Site: lung, lower lobe
C34.3

9-5-12
RD

Pathologist:

9/21/12

Source: NCI Genomic Data Commons file 127369a0-59b9-4b70-9e46-15ef7db8fe7b (TCGA-58-A46K.526A34E6-B8D1-4A05-B6E9-1CDDA281BD7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).